Somatic mutation profile of tumor specimen TCGA-EL-A4KD-01A (aliquot TCGA-EL-A4KD-01A-11D-A257-08) from TCGA case TCGA-EL-A4KD, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 41.9 years (15,291 days).
Specimen TCGA-EL-A4KD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b3140e2-b396-43df-8bbf-045c5df2b38c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A4KD-11A (Solid Tissue Normal), aliquot TCGA-EL-A4KD-11A-11D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae1678e4-ef71-49e7-8973-fd7bdad61340

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 7, Silent 5, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DOCK7 | c.2080C>G p.P694A | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.932); catalogued as COSV51997365; called by muse, mutect2, varscan2
- ECSIT | c.945+1G>A p.X315_splice | Splice Site (SNP) | VAF 22/69 reads (32%) | catalogued as COSV52938726; called by muse, mutect2, varscan2
- GABRA2 | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62912418; called by muse, mutect2, varscan2
- GPR139 | c.32A>T p.N11I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV58501852; called by muse, mutect2
- IRF5 | c.1416G>T p.Q472H | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV50856815; called by muse, mutect2, varscan2
- IRS2 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65477413; called by muse, mutect2, varscan2
- PDE4DIP | c.2546A>G p.Q849R | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1553539585, COSV57680007; called by muse, mutect2
- S100A7 | c.255C>A p.D85E | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as COSV64193107; called by muse, mutect2, varscan2
- TMEM145 | c.1033C>T p.Q345* | Nonsense Mutation (SNP) | VAF 7/83 reads (8%) | catalogued as rs1253586800, COSV56623952; called by muse, mutect2
- ALG13 | c.687A>G p.L229= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV52635776; called by muse, mutect2, varscan2
- GCN1 | c.5211A>G p.P1737= | Silent (SNP) | VAF 63/176 reads (36%) | catalogued as COSV56104507; called by muse, mutect2, varscan2
- NDST4 | c.192G>A p.E64= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV52110571; called by muse, mutect2
- SEC14L2 | c.843C>T p.S281= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs957935570, COSV57240286; called by mutect2, varscan2
- SLC9A3R1 | c.651C>A p.S217= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV52852630, COSV52854224; called by muse, mutect2, varscan2
